Somatic mutation profile of tumor specimen TCGA-2Z-A9J8-01A (aliquot TCGA-2Z-A9J8-01A-11D-A42J-10) from TCGA case TCGA-2Z-A9J8, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 50.6 years (18,498 days).
Specimen TCGA-2Z-A9J8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b88b8360-cea7-41e8-a727-69fb8a6d63bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9J8-10A (Blood Derived Normal), aliquot TCGA-2Z-A9J8-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e12e0534-d41c-493b-b37f-61486e2ad818

The open-access MAF lists 31 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Frame Shift Del 4, Frame Shift Ins 3, Silent 3, Splice Site 2, Splice Region 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG5 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.283); catalogued as COSV99575049; called by muse, mutect2
- CAMSAP2 | c.2590del p.T864Lfs*20 (on ENST00000236925 / NM_001297707.2; = p.T853Lfs*20 on NM_203459.3) | Frame Shift Del (DEL) | VAF 104/302 reads (34%) | catalogued as COSV52668167; called by mutect2, pindel, varscan2
- CLK4 | c.476-1G>C p.X159_splice | Splice Site (SNP) | VAF 70/223 reads (31%) | catalogued as COSV100308778; called by muse, mutect2, varscan2
- CUL3 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 102/238 reads (43%) | catalogued as COSV100023589; called by muse, mutect2, varscan2
- DIAPH2 | c.766A>C p.S256R | Missense Mutation (SNP) | VAF 228/289 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100230149; called by muse, mutect2, varscan2
- DOT1L | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101288480; called by muse, mutect2, varscan2
- DPF2 | c.229C>T p.R77W | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1565531873, COSV99361275; called by muse, mutect2, varscan2
- ERBB4 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53512360, COSV99614615; called by muse, mutect2, varscan2
- GPRASP1 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100850891, COSV100851016; called by muse, mutect2, varscan2
- MS4A7 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as COSV100279297; called by muse, mutect2, varscan2
- NAAA | c.902+1G>C p.X301_splice | Splice Site (SNP) | VAF 62/143 reads (43%) | catalogued as COSV99715708; called by muse, mutect2, varscan2
- NCBP2 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs766744099, COSV100051707; called by muse, mutect2
- PSMB5 | c.428C>G p.A143G | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV100557245; called by muse, mutect2, varscan2
- RAPGEF3 | c.967G>A p.A323T (on ENST00000389212; = p.A281T on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99405650; called by muse, mutect2
- RRAGA | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100998072; called by muse, mutect2, varscan2
- SLC14A2 | c.2302C>T p.L768F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs897790651, COSV54916015, COSV99674828; called by muse, mutect2, varscan2
- SLX4 | c.554A>C p.D185A | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV99567490; called by muse, mutect2, varscan2
- STAP1 | c.70C>A p.L24I | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99609068; called by muse, mutect2, varscan2
- WDR90 | c.1423C>G p.H475D | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.025); catalogued as COSV99552509; called by muse, mutect2, varscan2
- ZBTB17 | c.-2C>T | Splice Region (SNP) | VAF 24/41 reads (59%) | catalogued as COSV100998959; called by muse, mutect2, varscan2
- ZNF236 | c.3859C>G p.R1287G | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99468586; called by muse, mutect2, varscan2
- AC100868.1 | c.1508del p.F503Sfs*14 | Frame Shift Del (DEL) | VAF 40/93 reads (43%) | called by mutect2, pindel, varscan2
- CUL3 | c.63del p.P22Rfs*2 | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | called by mutect2, pindel, varscan2
- FAM110C | c.383dup p.P130Afs*3 | Frame Shift Ins (INS) | VAF 16/49 reads (33%) | called by pindel, varscan2
- NIPBL | c.3125_3141del p.S1042Ifs*7 | Frame Shift Del (DEL) | VAF 52/135 reads (39%) | called by mutect2, pindel, varscan2
- TTYH3 | c.1214_1217dup p.C407Rfs*15 | Frame Shift Ins (INS) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- ZFYVE9 | c.3388dup p.M1130Nfs*7 | Frame Shift Ins (INS) | VAF 40/109 reads (37%) | called by mutect2, pindel, varscan2
- CATSPERE | c.408G>A p.G136= | Silent (SNP) | VAF 124/295 reads (42%) | catalogued as COSV100834849; called by muse, mutect2, varscan2
- MAPK15 | c.1404G>T p.L468= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as COSV100567647; called by muse, mutect2, varscan2
- RASGRP4 | c.1029C>T p.C343= | Silent (SNP) | VAF 65/140 reads (46%) | catalogued as rs759575924, COSV99498348; called by muse, mutect2, varscan2
- ANKRD33 | c.-336C>A | 5'UTR (SNP) | VAF 43/93 reads (46%) | catalogued as COSV100001071, COSV100001353; called by muse, mutect2, varscan2
